CCDI case PBCMJM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/a1b78c03-c36d-4c4c-899b-74d246a63d03

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 13.0 years (4,731 days).

Biospecimens (3 samples)
- Sample 0DW72K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW744: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
